Somatic mutation profile of tumor specimen TCGA-S9-A7QW-01A (aliquot TCGA-S9-A7QW-01A-11D-A34A-08) from TCGA case TCGA-S9-A7QW, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 54.4 years (19,869 days).
Specimen TCGA-S9-A7QW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 885662ac-4932-4d5f-9a5c-2149cceaef79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A7QW-10A (Blood Derived Normal), aliquot TCGA-S9-A7QW-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdc32b64-5fd7-4387-8e32-8297466f2a61

The open-access MAF lists 39 somatic variants for this specimen: 25 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 21, Silent 14, Nonsense Mutation 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 36/86 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 28/30 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: drug response / pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AP002512.3 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs777835699, COSV54405581; called by muse, mutect2, varscan2
- CCDC185 | c.403T>A p.C135S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV100838848; called by muse, varscan2
- CR1L | c.617A>T p.Y206F | Missense Mutation (SNP) | VAF 90/201 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.397); catalogued as COSV99688174; called by muse, mutect2, varscan2
- DNMT3A | c.2161A>G p.K721E | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV99265127; called by muse, mutect2, varscan2
- FGD5 | c.2689G>A p.A897T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs746373403, COSV99549585; called by muse, mutect2, varscan2
- LIMK1 | c.601G>T p.V201F | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100283528; called by muse, mutect2, varscan2
- MTMR1 | c.1104A>T p.E368D | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.291); catalogued as COSV100953168; called by muse, mutect2, varscan2
- NEK11 | c.1412A>G p.D471G | Missense Mutation (SNP) | VAF 13/317 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV101273248; called by muse, mutect2
- NT5DC3 | c.799A>G p.I267V | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV101231055; called by muse, mutect2, varscan2
- PELP1 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as rs757402798, COSV99343517; called by muse, mutect2, varscan2
- PLXNB3 | c.709G>C p.A237P | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100738043, COSV62803167; called by muse, mutect2, varscan2
- PRDM9 | c.1740T>G p.Y580* | Nonsense Mutation (SNP) | VAF 48/107 reads (45%) | catalogued as COSV99691493; called by muse, mutect2, varscan2
- SAP130 | c.1856C>G p.S619* | Nonsense Mutation (SNP) | VAF 34/59 reads (58%) | catalogued as COSV52094047, COSV99385493; called by muse, mutect2, varscan2
- SERPINA5 | c.949G>T p.V317F | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as COSV100291881; called by muse, mutect2, varscan2
- SYT16 | c.992A>G p.E331G | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV101413699; called by muse, mutect2, varscan2
- TMEM33 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1456185374, COSV100048978; called by muse, mutect2, varscan2
- TRIM50 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs145742720; called by muse, mutect2, varscan2
- USP19 | c.1336A>T p.T446S | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.091); catalogued as COSV100026607; called by muse, mutect2, varscan2
- USP9X | c.5061A>C p.L1687F | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.238); catalogued as COSV100200271; called by muse, mutect2
- ZNF7 | c.1802G>A p.R601K | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV100296185, COSV57384111; called by muse, mutect2, varscan2
- ATRX | c.1191dup p.V398Cfs*4 | Frame Shift Ins (INS) | VAF 204/565 reads (36%) | called by mutect2, pindel, varscan2
- CDKN1B | c.156_165dup p.S56Gfs*72 | Frame Shift Ins (INS) | VAF 16/72 reads (22%) | called by mutect2, varscan2
- LRP1B | c.10742G>A p.G3581E | Missense Mutation (SNP) | VAF 7/191 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- DNAI4 | c.2253C>T p.Y751= | Silent (SNP) | VAF 60/110 reads (55%) | catalogued as rs369539029; called by muse, mutect2, varscan2
- GBGT1 | c.798G>A p.G266= | Silent (SNP) | VAF 36/154 reads (23%) | catalogued as COSV100923797; called by muse, mutect2, varscan2
- NAIP | c.249C>T p.A83= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as rs781416187, COSV52003623; called by muse, mutect2, varscan2
- OR2AE1 | c.459C>T p.S153= | Silent (SNP) | VAF 31/133 reads (23%) | catalogued as rs200183500; called by muse, mutect2, varscan2
- OSCAR | c.117G>A p.L39= | Silent (SNP) | VAF 35/52 reads (67%) | catalogued as COSV99500125; called by muse, mutect2, varscan2
- PAQR8 | c.795C>T p.P265= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as rs751244572, COSV100658559, COSV62442184; called by muse, mutect2, varscan2
- PRPF31 | c.828C>T p.H276= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as CD033222, COSV100320157; called by muse, mutect2, varscan2
- PWWP3B | c.810T>C p.S270= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV100531696; called by muse, mutect2, varscan2
- TRABD | c.765C>T p.I255= | Silent (SNP) | VAF 58/132 reads (44%) | catalogued as rs1308489609, COSV57712691; called by muse, mutect2, varscan2
- TXNDC12 | c.132A>G p.E44= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as COSV100860927; called by muse, mutect2, varscan2
- USP20 | c.141C>T p.A47= | Silent (SNP) | VAF 34/163 reads (21%) | catalogued as COSV100204891; called by muse, mutect2, varscan2
- VPS13D | c.12789C>T p.D4263= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as rs747824711, COSV50695525; called by muse, mutect2, varscan2
- ZBTB38 | c.621C>T p.D207= | Silent (SNP) | VAF 37/81 reads (46%) | catalogued as rs1424502411, COSV100375198; called by muse, mutect2, varscan2
- ZMYM3 | c.1395T>C p.P465= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100078505; called by muse, varscan2
